Surgical pathology report (de-identified scan), TCGA case TCGA-CS-4942, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-4942-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED] TCGA-CS-4942

FINAL DIAGNOSIS:

1. Right insular tumor: astrocytoma with mitotic activity. see comment.
2. Right insular tumor: astrocytoma with mitotic activity. see comment.

Comment:

The tumor in specimens #1 and #2 contains fibrillary astrocytoma composed of moderately pleomorphic fibrillary astrocytes. Rare but multiple mitoses are present in both specimens #1 and #2. Two mitotic figures are identified in specimen #1 (slide 1B) and two mitotic figures are identified in specimen #2 (slide 2B). The proliferation index as determined by Ki67 (MIB-1) staining is greater than 5% in small foci of specimen #2 (slide 2A). The identification of rare mitoses and a focally elevated proliferation index suggest that this astrocytic tumor is an astrocytoma (WHO grade II) in the process of transformation to a higher grade tumor or that these tumor biopsies are from a higher grade tumor. Clinical correlation recommended.

[REDACTED]

Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

[REDACTED]

Frozen Section Diagnosis:

1. Atypical glial cells, highly suspicious for fibrillar astrocytoma. Case discussed with [REDACTED]
2. Astrocytoma. No high-grade features identified on representative

[page 2 of 3]
zen section.

Clinical History and Diagnosis:

Right insular tumor, consistent with glioma

Source of Specimen:

1: Right insular tumor

2: Right insular tumor

Gross Description:

1. Right insular tumor: Received fresh are multiple fragments of red-tan soft tissue measuring 1.0 x 0.5 x 0.2 cm in aggregate. Touch preparation slides are created and one half of the specimen is submitted in one cassette for frozen section. The remainder of the specimen is entirely submitted in one cassette for permanent section.

Designations:

A. frozen section control

B. remainder of specimen

2. Right insular tumor: Received fresh are multiple fragments of red-tan soft tissue measuring 1.1 x 1.0 x 0.3 cm in aggregate. Touch preparation slides are created and one half of the specimen is submitted in one cassette for frozen section. The remainder of the specimen is entirely submitted in one cassette for permanent section.

Designations:

A. frozen section control

B. remainder of specimen

Histology Laboratory

H&E

Part 2: Right insular tumor

DEEPER

DEEPER

UNSTAINED

[page 3 of 3]
[REDACTED]

[REDACTED]

IMMUNOPATHOLOGY
DIAGNOSIS

gfap: positive staining in glial tissue including astrocytic neoplasm.

ki67 (MIB-1): positive staining in scattered tumor cell nuclei. small foci of tumor show positive staining in approximately 7% of tumor cell nuclei.

Comment:

See corresponding surgical pathology report [REDACTED]

[REDACTED] Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory
([REDACTED]) record.
[REDACTED]

Specimen(s) Received:

1: RT INSULAR TUMOR

Source: NCI Genomic Data Commons file 3ee3bd1d-b8db-4c5c-83f8-a4d56f3af638 (TCGA-CS-4942.052C9FF3-16AD-4219-8839-488297BEAD1F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).